Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1XF, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1XF-01A (Primary Tumor).

Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination

Internal invoice No.

Value of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age: Gender: F

Material: Multiple organ resection – left breast with axillary tissues

Unit in charge:

Physician in charge:

Material collected on: Material received on:

Expected time of examination: up to 8 working days

Clinical diagnosis: Cancer of the left breast.

Examination performed on:

Macroscopic description:

Left breast sized 22 x 15 x 4 cm removed along with axillary tissues sized 10 x 6 x 2 cm and a 17 x 6.5 cm skin flap. Weight 780 g.

A post-operative scar visible round the nipple with a site of 6 x 4 x 2 cm.

Microscopic description:

Infiltratio carcinomatosa mamillae.

Status post resectionem tumoris.

Glandular tissue containing foci of carcinoma ductale in situ (solid and cribrate type, with medium nuclear atypia, with necrosis and calcifications, as well as lesions of the type mastopathia fibrosa.

Axillary lymph nodes:

Lymphonodulitis chronica (No VIII).

Preliminary result:

(including the examination No. ')

Carcinoma invasivum mammae sinistrae.
(NHG2, pT2, pN0).

hw 4/12/11

Compliance validated by:

Examination performed on:

Histopathological diagnosis:

Carcinoma ductale invasivum mammae sinistrae. Invasive ductal carcinoma of the left breast. #
NHG2, pT2, pN0.

Compliance validated by:

Source: NCI Genomic Data Commons file 2a80a5f0-4457-41b8-afcf-53039ebb64de (TCGA-D8-A1XF.FCBB54EB-6FBF-4DC4-B4D5-DB533687FA58.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).